Surgical pathology report (de-identified scan), TCGA case TCGA-05-4402, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Indivumed, specimen TCGA-05-4402-01A (Primary Tumor).

Main diagnosis/diagnoses:

Mixed adenocarcinoma located peripherally in the lower lobe with a predominant acinar component, a smaller large-cell solid component with a bronchioloalveolar growth pattern in the tumor periphery, slight mucin formation and marked lymph vessel propagation in the lung tissue and the visceral pleura.

Comment/supplementary remark:

Conventional histology shows a peripheral bronchopulmonary carcinoma (to be verified by immunohistological analysis). The tumor has infiltrated the visceral pleura, focally penetrated the surface of the pleura and extends as far as the basal margin of the preparation after the row of metal clamps is removed.

These findings thus give a tumor classification of pT2 pNX pMX L1 RX, with localization code C34.3 and morphology code M8255/3.

Source: NCI Genomic Data Commons file 31e13be6-4140-4ded-9322-50089b950024 (TCGA-05-4402.8099C860-5C8D-4200-8C8F-07F9E1B71780.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).